Somatic mutation profile of tumor specimen TCGA-GJ-A9DB-01A (aliquot TCGA-GJ-A9DB-01A-11D-A36X-10) from TCGA case TCGA-GJ-A9DB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.5 years (25,020 days).
Specimen TCGA-GJ-A9DB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b017587-63ed-4773-a838-0d6411ac98c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GJ-A9DB-10A (Blood Derived Normal), aliquot TCGA-GJ-A9DB-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/caa00c9f-f1b3-447b-8497-cac83c91b56c

The open-access MAF lists 91 somatic variants for this specimen: 60 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 28, Nonsense Mutation 4, Frame Shift Del 3, 3'UTR 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3597G>T p.E1199D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as COSV99969639; called by muse, mutect2, varscan2
- ANKRD50 | c.2431G>A p.D811N | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746316320, COSV101538982; called by muse, mutect2, varscan2
- AP4E1 | c.2647A>G p.M883V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs774302336, COSV99956727; called by muse, mutect2, varscan2
- AREL1 | c.2204G>A p.W735* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as COSV100707622; called by muse, mutect2, varscan2
- BCO2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs764094222, COSV63062697, COSV63064809; called by muse, mutect2, varscan2
- BIN1 | c.1466C>A p.S489Y (on ENST00000316724 / NM_001320642.1; = p.S350Y on NM_004305.4) | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99388119; called by muse, mutect2, varscan2
- BNC2 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as COSV101033474; called by muse, mutect2, varscan2
- BUD23 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV99736659; called by muse, mutect2
- CCT6A | c.1070A>G p.E357G | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV99303508; called by muse, mutect2, varscan2
- CD5L | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63821174, COSV63821298; called by muse, mutect2, varscan2
- CDKL1 | c.46T>C p.Y16H | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99367572; called by muse, mutect2, varscan2
- CHD5 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); catalogued as COSV99313852; called by muse, mutect2, varscan2
- CLCN2 | c.1831A>T p.M611L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99658656; called by muse, mutect2, varscan2
- CNTN2 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085121; called by muse, mutect2, varscan2
- CUBN | c.5749A>G p.S1917G | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV100912831; called by muse, mutect2, varscan2
- CYBA | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as COSV99879954; called by muse, mutect2
- CYP4A22 | c.1177C>T p.L393F | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV53739371; called by muse, mutect2, varscan2
- DHX37 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100439292; called by muse, mutect2, varscan2
- DPP9 | c.2244G>T p.K748N (on ENST00000598800; = p.K777N on NM_139159.5) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99506197; called by muse, mutect2, varscan2
- EFL1 | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99187253; called by muse, mutect2, varscan2
- FHOD1 | c.3308C>T p.T1103I | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1232404830, COSV50770843; called by muse, mutect2, varscan2
- FOXN2 | c.984G>C p.E328D | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.967); catalogued as COSV100489260; called by muse, mutect2, varscan2
- HLA-DQA1 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100568121; called by muse, mutect2, varscan2
- INTU | c.1526G>C p.R509T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100080933; called by muse, mutect2, varscan2
- KATNB1 | c.1295A>C p.N432T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV101109220; called by muse, mutect2, varscan2
- KCNB2 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101578820, COSV73052979; called by muse, mutect2, varscan2
- KIF13A | c.1076A>T p.N359I | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99436319; called by muse, mutect2, varscan2
- LGALS8 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99436516; called by muse, mutect2, varscan2
- LMBR1L | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99908864; called by muse, mutect2, varscan2
- MOGS | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.108); catalogued as rs1371981055, COSV99270564; called by muse, mutect2, varscan2
- MTAP | c.426G>C p.E142D | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV101205471, COSV66476956; called by muse, mutect2, varscan2
- MTMR14 | c.1614-1G>T p.X538_splice | Splice Site (SNP) | VAF 28/53 reads (53%) | catalogued as rs1373577450, COSV56006836, COSV99931340; called by muse, mutect2, varscan2
- MYO3A | c.2329G>C p.D777H | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56317982, COSV99780039; called by muse, mutect2, varscan2
- MYPOP | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.029); catalogued as COSV100138906; called by muse, mutect2, varscan2
- NFXL1 | c.1817C>A p.T606N | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.093); catalogued as COSV100216837; called by muse, mutect2, varscan2
- NLRC3 | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs774299870, COSV57089934; called by muse, mutect2
- NUP133 | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748657208, COSV99773004; called by muse, mutect2, varscan2
- NXPE4 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100970463; called by muse, mutect2, varscan2
- OR52E4 | c.226T>C p.S76P | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs779512897, COSV100389270; called by muse, mutect2, varscan2
- PAICS | c.218T>G p.I73S | Missense Mutation (SNP) | VAF 58/222 reads (26%) | PolyPhen probably damaging (0.976); catalogued as COSV99947820; called by muse, mutect2, varscan2
- PCDHA11 | c.1622T>G p.V541G | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100251146; called by muse, mutect2, varscan2
- PIGZ | c.1127T>G p.M376R | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV99433839; called by muse, mutect2, varscan2
- PTPRD | c.2013A>C p.K671N | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV100645110; called by muse, mutect2, varscan2
- SBNO2 | c.1177A>G p.K393E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV100684641; called by muse, mutect2, varscan2
- SLC25A42 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236169194, COSV100588111; called by muse, mutect2, varscan2
- SLC39A8 | c.58G>T p.G20* | Nonsense Mutation (SNP) | VAF 36/115 reads (31%) | catalogued as COSV100765766, COSV63221937; called by muse, mutect2, varscan2
- SMCO1 | c.50G>A p.R17K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1413855719, COSV101285010; called by muse, mutect2, varscan2
- SPN | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.104); catalogued as COSV100788807; called by muse, mutect2, varscan2
- TRPS1 | c.1429A>G p.R477G (on ENST00000220888 / NM_001330599.2; = p.R490G on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1314031779, COSV99631519; called by muse, mutect2, varscan2
- TSPAN15 | c.344C>A p.T115N | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV100960368; called by muse, mutect2
- USP49 | c.107G>A p.W36* | Nonsense Mutation (SNP) | VAF 32/89 reads (36%) | catalogued as COSV99790306; called by muse, mutect2, varscan2
- VPS54 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); catalogued as COSV99708224; called by muse, mutect2, varscan2
- ZBTB2 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.117); catalogued as rs773940061, COSV100287693; called by muse, mutect2, varscan2
- ZNF442 | c.740C>G p.P247R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV54420703, COSV54422260; called by muse, mutect2, varscan2
- ZNF565 | c.151G>A p.V51M (on ENST00000355114; = p.V11M on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766175480, COSV100411896; called by muse, mutect2, varscan2
- ZNF619 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59029455; called by muse, mutect2, varscan2
- IGKV2-30 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RASGRF2 | c.1494del p.F498Lfs*6 | Frame Shift Del (DEL) | VAF 30/134 reads (22%) | called by mutect2, pindel, varscan2
- SRCAP | c.7219_7223del p.Q2407Gfs*34 | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | called by mutect2, pindel, varscan2
- TP73 | c.186+1del | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | called by mutect2, pindel, varscan2
- AARS2 | c.1713G>A p.Q571= | Silent (SNP) | VAF 60/175 reads (34%) | catalogued as COSV99771493; called by muse, mutect2, varscan2
- ALB | c.978G>A p.L326= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV99891588; called by muse, mutect2, varscan2
- ARHGAP10 | c.687G>A p.Q229= | Silent (SNP) | VAF 38/218 reads (17%) | catalogued as COSV100331315; called by muse, mutect2, varscan2
- CASKIN1 | c.498G>A p.L166= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs762748655, COSV100624172; called by muse, mutect2, varscan2
- COL8A2 | c.279C>G p.P93= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100291221; called by muse, mutect2, varscan2
- DKK3 | c.450C>T p.D150= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs918670099, COSV100485036; called by muse, mutect2, varscan2
- EBF3 | c.195C>A p.S65= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100799291; called by muse, mutect2, varscan2
- FAT3 | c.2412T>C p.Y804= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV99966909; called by muse, mutect2, varscan2
- FLNC | c.213C>T p.I71= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as COSV57952546; called by muse, mutect2, varscan2
- FOXD3 | c.168C>T p.D56= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as COSV100942898; called by muse, mutect2, varscan2
- HIVEP3 | c.5181G>A p.P1727= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs753210157, COSV56018691; called by muse, mutect2, varscan2
- LTB4R | c.945G>A p.T315= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1395887196; called by muse, mutect2
- MCOLN1 | c.978G>A p.L326= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV99900663; called by muse, mutect2, varscan2
- MYBBP1A | c.1662T>C p.N554= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs769235541, COSV54594940, COSV99626255; called by muse, mutect2, varscan2
- OLIG2 | c.585C>A p.S195= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100324284; called by muse, mutect2, varscan2
- OR8A1 | c.390G>A p.L130= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV99420628; called by muse, mutect2, varscan2
- POTED | c.1692G>A p.K564= | Silent (SNP) | VAF 77/273 reads (28%) | catalogued as COSV100203155; called by muse, mutect2, varscan2
- PRG4 | c.2445T>C p.S815= | Silent (SNP) | VAF 56/135 reads (41%) | catalogued as COSV63354771; called by muse, mutect2, varscan2
- RBM27 | c.3069T>A p.T1023= | Silent (SNP) | VAF 160/367 reads (44%) | catalogued as COSV99506239; called by muse, mutect2, varscan2
- SLC28A3 | c.1794G>A p.G598= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100883266; called by muse, mutect2, varscan2
- ST18 | c.1413G>A p.V471= | Silent (SNP) | VAF 65/186 reads (35%) | catalogued as COSV99389925; called by muse, mutect2, varscan2
- TMEM130 | c.1179C>T p.V393= (on ENST00000416379 / NM_001134450.2; = p.V381= on NM_152913.3) | Silent (SNP) | VAF 92/251 reads (37%) | catalogued as COSV100228822; called by muse, mutect2, varscan2
- TOLLIP | c.447C>T p.D149= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV99719596; called by muse, mutect2, varscan2
- TRIML1 | c.309G>A p.K103= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as COSV100206060; called by muse, mutect2, varscan2
- TRPV5 | c.708C>A p.P236= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as COSV99520617; called by muse, varscan2
- TTBK1 | c.624C>T p.V208= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs748186107, COSV99444777; called by muse, mutect2, varscan2
- VN1R2 | c.267G>T p.G89= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as COSV100447982; called by muse, mutect2, varscan2
- ZCRB1 | c.42A>T p.V14= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV99861269; called by muse, mutect2, varscan2
- ABCA5 | c.*1A>G | 3'UTR (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99288728; called by muse, mutect2, varscan2
- KDM1A | c.518-5927G>C | Intron (SNP) | VAF 19/109 reads (17%) | catalogued as COSV100752630; called by muse, mutect2, varscan2
- ZIC2 | c.*2G>T | 3'UTR (SNP) | VAF 190/345 reads (55%) | catalogued as COSV100891758, COSV100891783; called by muse, mutect2, varscan2
